Somatic mutation profile of tumor specimen TCGA-EV-5901-01A (aliquot TCGA-EV-5901-01A-11D-1589-08) from TCGA case TCGA-EV-5901, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 47.3 years (17,275 days).
Specimen TCGA-EV-5901-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e038281-bdfc-4bbe-9ced-269001e8b8a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EV-5901-10A (Blood Derived Normal), aliquot TCGA-EV-5901-10A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/add56bc1-3fe3-4e6a-8801-ba830b496d5e

The open-access MAF lists 45 somatic variants for this specimen: 35 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 7, Frame Shift Del 3, Splice Site 2, Intron 2, Nonsense Mutation 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA5 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 94/180 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746299297, COSV67017158; called by muse, mutect2, varscan2
- ANK3 | c.4456A>G p.R1486G | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.631); catalogued as rs1294897783, COSV55061422, COSV99781522; called by muse, mutect2, varscan2
- ANP32E | c.341A>C p.N114T | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV58482432; called by muse, mutect2, varscan2
- ARHGAP30 | c.1394G>T p.G465V | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV63516979; called by muse, mutect2, varscan2
- CEMIP | c.3407G>A p.G1136E | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54993997; called by muse, mutect2, varscan2
- CNNM4 | c.604C>A p.L202I | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV65661120; called by muse, mutect2, varscan2
- CSNK2A1 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); catalogued as COSV53935384; called by muse, mutect2, varscan2
- DDX3X | c.455G>A p.G152E (on ENST00000399959; = p.G153E on NM_001356.5) | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.519); catalogued as COSV67863772, COSV67863934; called by muse, mutect2, varscan2
- DNAJC2 | c.839T>A p.I280K | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV50790970; called by muse, mutect2, varscan2
- DNAJC2 | c.838A>T p.I280L | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); catalogued as COSV50790986; called by muse, mutect2, varscan2
- EPHA6 | c.2162A>C p.D721A (on ENST00000389672 / NM_001080448.3; = p.D113A on NM_173655.4) | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67575333; called by muse, mutect2, varscan2
- GUCY2C | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.303); catalogued as rs756228942, COSV53791056; called by muse, mutect2, varscan2
- HMOX1 | c.54G>T p.K18N | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53340011; called by muse, mutect2, varscan2
- NHLH1 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs1431620541, COSV57483728; called by muse, mutect2
- NSUN2 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as COSV52954852; called by muse, mutect2, varscan2
- PDGFRA | c.1495G>A p.V499M | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs746574289, COSV57264113; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHC3 | c.1037C>T p.P346L (on ENST00000494943 / NM_001308116.2; = p.P358L on NM_024947.4) | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV71948800; called by muse, mutect2, varscan2
- PLEC | c.6800A>T p.Q2267L (on ENST00000322810 / NM_201380.4; = p.Q2157L on NM_000445.5) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV59643888; called by muse, mutect2, varscan2
- POLRMT | c.1856G>A p.G619D | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52115194; called by muse, mutect2
- PPP1R10 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as COSV64739359; called by muse, mutect2, varscan2
- PSMD6 | c.826+1G>T p.X276_splice | Splice Site (SNP) | VAF 10/32 reads (31%) | catalogued as COSV55760078; called by muse, varscan2
- RAB3A | c.57C>G p.F19L | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV55852858; called by muse, mutect2, varscan2
- RNF115 | c.786T>A p.H262Q | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV65164734; called by muse, mutect2, varscan2
- SACS | c.8543T>A p.F2848Y | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV66540983; called by muse, mutect2, varscan2
- SLC22A5 | c.1586+1G>A p.X529_splice | Splice Site (SNP) | VAF 61/149 reads (41%) | catalogued as COSV55373196; called by muse, mutect2, varscan2
- SUN2 | c.497T>C p.L166P | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV53304414; called by muse, mutect2, varscan2
- TERT | c.2566G>T p.G856W | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57218382; called by muse, mutect2
- URGCP | c.878T>G p.F293C (on ENST00000453200 / NM_001077663.3; = p.F284C on NM_017920.4) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56248348; called by muse, mutect2, varscan2
- VCAN | c.7991A>G p.D2664G | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV54106801; called by muse, mutect2, varscan2
- VPS54 | c.385A>T p.K129* | Nonsense Mutation (SNP) | VAF 20/59 reads (34%) | catalogued as COSV55441321; called by muse, mutect2, varscan2
- ZNF106 | c.5097T>G p.H1699Q | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104378133, COSV55517401; called by muse, mutect2, varscan2
- BSN | c.9481del p.Y3161Mfs*3 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by pindel*, varscan2
- CD86 | c.618_619del p.F207Pfs*2 (on ENST00000330540 / NM_175862.5; = p.F201Pfs*2 on NM_006889.4) | Frame Shift Del (DEL) | VAF 157/378 reads (42%) | called by mutect2, pindel, varscan2
- CEP63 | c.283del p.E95Nfs*6 | Frame Shift Del (DEL) | VAF 34/81 reads (42%) | called by mutect2, pindel, varscan2
- ITPRID1 | c.2540_2545del p.T847_L848del | In Frame Del (DEL) | VAF 38/121 reads (31%) | called by mutect2, pindel, varscan2
- ABCA2 | c.4425C>G p.V1475= (on ENST00000614293; = p.V1445= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV55802297; called by muse, mutect2, varscan2
- ARID5A | c.672G>A p.G224= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV62591222; called by muse, mutect2, varscan2
- AXIN1 | c.1125C>T p.Y375= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as rs1280503610, COSV51988360; called by muse, mutect2
- B3GLCT | c.321A>G p.A107= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as rs770487360, COSV58455734; called by muse, mutect2, varscan2
- BAZ1B | c.624A>G p.G208= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV59991691; called by muse, mutect2, varscan2
- KDM2B | c.1185G>A p.R395= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV65641660; called by muse, mutect2, varscan2
- LPCAT1 | c.630T>A p.T210= | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as COSV52038189; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503527 G>A | 5'Flank (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- NCAPD2 | c.262+169A>T | Intron (SNP) | VAF 8/226 reads (4%) | catalogued as COSV100217307, COSV59697941; called by muse, mutect2
- PDE4A | c.320+9944C>A | Intron (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
